Somatic mutation profile of tumor specimen TCGA-G9-6347-01A (aliquot TCGA-G9-6347-01A-11D-A31L-08) from TCGA case TCGA-G9-6347, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 59.5 years (21,721 days).
Specimen TCGA-G9-6347-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71f62346-3193-4be4-8346-aabb4c8e7eca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6347-10A (Blood Derived Normal), aliquot TCGA-G9-6347-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/520c3f22-1f49-4cdb-9fa9-ae94c9efbc91

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP70 | c.578T>C p.M193T | Missense Mutation (SNP) | VAF 26/306 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV60284884; called by muse, mutect2
- FSCN3 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs146886586; called by muse, mutect2, varscan2
- KLHDC7A | c.455A>G p.N152S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV68770309; called by muse, mutect2
- MDM1 | c.1007T>C p.V336A | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100291946, COSV57447522; called by muse, mutect2
- OR8K1 | c.388G>A p.V130I | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as rs1405594221, COSV54401343; called by muse, mutect2
- PCDHA7 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV65345546; called by muse, mutect2
- SF3B1 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV59207586; called by muse, mutect2, varscan2
- TIAM2 | c.3206A>T p.N1069I | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV51642294; called by muse, mutect2
- MYLK | c.3900G>A p.A1300= | Silent (SNP) | VAF 24/262 reads (9%) | catalogued as rs563116446, COSV60613110; ClinVar: uncertain significance; called by muse, mutect2
- PKD1 | c.11313G>A p.S3771= (on ENST00000262304 / NM_001009944.3; = p.S3770= on NM_000296.4) | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs776847185, COSV51912482; called by muse, mutect2
- PRKD1 | c.1476C>T p.F492= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as rs1050229277, COSV59558823; called by muse, mutect2
- PRRC2B | c.6237A>T p.P2079= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV57645579; called by muse, mutect2
- SCN5A | c.2595C>T p.Y865= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV61131113; called by muse, mutect2
- SLCO4A1 | c.480C>T p.V160= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV53892222; called by muse, mutect2, varscan2
- ZNF783 | c.802+3383G>A | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV65185953; called by muse, mutect2, varscan2
